Gene-level copy-number profile of tumor specimen HCM-SANG-0271-D12-31B from HCMI case HCM-SANG-0271-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Tubular adenoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0271-D12-31B: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 608fe96d-f764-4731-93a2-0409c64b6dbb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0271-D12-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/2c90cc48-39cd-42ae-9366-95311ef552b2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 9; copy number 2: 49; copy number 3: 2,849; copy number 4: 23,170; copy number 5: 12,211; copy number 6: 12,191; copy number 7: 5,275; copy number 8: 1,542; copy number 9: 221; copy number 11: 15; copy number 12: 25; copy number 14: 649; copy number 15: 3; copy number 16: 2; copy number 19: 179.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,702,379–1,745,992, 4 genes (within-gene range 0–4): CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr1:12,838,125–12,841,357, 1 gene: PRAMEF30P.
- chr21:9,068,361–9,129,752, 3 genes (within-gene range 0–3): TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,094 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:45,323,253–45,480,136, 3 genes, copy number 11: THAP12P9, AC108043.1, RNU6-931P.
- chr8:22,679,013–23,164,027, 17 genes, copy number 9: AC105046.1, EGR3, AC055854.1, AC105046.2, PEBP4, AC037441.1, AC037441.2, RN7SL303P, AC107959.1, RHOBTB2, TNFRSF10B, AC107959.2, AC107959.3, AC107959.4, AC107959.5, TNFRSF10C, TNFRSF10D.
- chr8:28,494,205–29,360,222, 20 genes, copy number 9: FZD3, MIR4288, RNA5SP259, EXTL3, EXTL3-AS1, INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1.
- chr8:34,784,028–37,095,390, 24 genes, copy number 9: LINC01288, AC087343.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4.
- chr12:17,710,934–17,711,046, 1 gene, copy number 9: Y_RNA.
- chr12:23,108,458–26,833,194, 57 genes, copy number 9 (within-gene range 6–9): AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2.
- chr13:41,955,808–46,753,040, 102 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr20:30,214,765–64,327,972, 870 genes, copy number 11–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
